Somatic mutation profile of tumor specimen TCGA-D6-6827-01A (aliquot TCGA-D6-6827-01A-11D-1912-08) from TCGA case TCGA-D6-6827, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lip, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 55.2 years (20,175 days).
Specimen TCGA-D6-6827-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a435b11b-0fbc-472e-8282-909a502d4354.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D6-6827-10A (Blood Derived Normal), aliquot TCGA-D6-6827-10A-01D-1912-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e983f880-ec27-4aa0-a004-0ecd8f324e62

The open-access MAF lists 16 somatic variants for this specimen: 12 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 9, Silent 4, Frame Shift Del 1, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACVR1B | c.1465C>T p.R489C | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752443171, COSV57777503; called by muse, mutect2, varscan2
- BCLAF1 | c.740T>C p.M247T | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.005); catalogued as rs751773151, COSV100786951; called by muse, mutect2, varscan2
- C22orf42 | c.223A>G p.M75V | Missense Mutation (SNP) | VAF 74/246 reads (30%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.043); catalogued as COSV101173373; called by muse, mutect2, varscan2
- CYLD | c.1544A>T p.D515V | Missense Mutation (SNP) | VAF 44/77 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100282727; called by muse, mutect2, varscan2
- DNAH9 | c.10066G>A p.A3356T | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.103); catalogued as COSV52365321; called by muse, varscan2
- ERAS | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.013); catalogued as rs782770684, COSV54433000; called by muse, mutect2
- F13B | c.37A>G p.I13V | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV100803420; called by muse, mutect2, varscan2
- FN1 | c.3350T>G p.L1117R | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100118132; called by muse, mutect2, varscan2
- MPDZ | c.1081T>A p.L361M | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV100064440; called by muse, mutect2, varscan2
- NFIB | c.969_970del p.L323Ffs*84 | Frame Shift Del (DEL) | VAF 30/89 reads (34%) | called by mutect2, pindel, varscan2
- PLXNB3 | c.4068dup p.P1357Afs*73 | Frame Shift Ins (INS) | VAF 19/37 reads (51%) | called by mutect2, pindel, varscan2
- SOX10 | c.723_734del p.P242_P245del | In Frame Del (DEL) | VAF 48/173 reads (28%) | called by mutect2, varscan2
- ADGRE5 | c.399C>T p.C133= | Silent (SNP) | VAF 15/174 reads (9%) | catalogued as rs552958951, COSV54414992; called by muse, mutect2
- BTC | c.240G>A p.G80= | Silent (SNP) | VAF 49/139 reads (35%) | catalogued as COSV67547565; called by muse, mutect2, varscan2
- COL6A3 | c.5037G>T p.G1679= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as COSV99800984; called by muse, mutect2, varscan2
- GDF10 | c.594C>T p.R198= | Silent (SNP) | VAF 27/58 reads (47%) | catalogued as rs1555207489; called by muse, mutect2, varscan2
